Gene-level copy-number profile of tumor specimen TCGA-HC-A8CY-01A from TCGA case TCGA-HC-A8CY, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.4 years (23,154 days).
Specimen TCGA-HC-A8CY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.61ce6880-449e-4705-9a3b-a51ee116e5a8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HC-A8CY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/43d9564b-e6b4-4df3-824d-b55010db4f03

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,522; copy number 2: 50,032; copy number 3: 2,626; copy number 4: 210; copy number 5: 1,324; copy number 6: 66; copy number 10: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HC-A8CY-01A-11D-A363-01): tumor purity 0.82, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,423 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–139,127,953, 1,324 genes, copy number 5 (broad region; genes not listed).
- chr16:46,469,341–50,151,731, 99 genes, copy number 6–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,396. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
